Somatic mutation profile of tumor specimen BA2986D (aliquot aq-BA2986D) from BEATAML1.0 case 2110, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.6 years (17,768 days).
Specimen BA2986D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ba9a3c-1a19-493d-81ed-e0000d32c583.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2794D (Solid Tissue Normal), aliquot aq-BA2794D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11b7b7bd-218f-450d-9422-0597769cec1b

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, 5'UTR 3, Nonsense Mutation 2, Intron 2, Frame Shift Del 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780536559, COSV52810410; called by muse, mutect2, varscan2
- BASP1 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV59470892; called by muse, mutect2
- GATA2 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV62003828, COSV62004430; called by mutect2, varscan2
- GNL3L | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs766343077, COSV60577766; called by muse, mutect2, varscan2
- GPR179 | c.2686C>T p.R896* (on ENST00000621958; = p.R895* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as rs764324380; called by muse, mutect2, varscan2
- GTPBP3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284052979; called by muse, mutect2, varscan2
- OLFM1 | c.180del p.K61Rfs*6 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs758132429; called by mutect2, pindel, varscan2
- OR10C1 | c.706C>T p.R236C (on ENST00000622521; = p.R234C on NM_013941.3) | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV65822505; called by muse, mutect2, varscan2
- PCDH1 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs756654044; called by muse, mutect2, varscan2
- SLCO1B3 | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53941117; called by muse, mutect2
- STAT4 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.187); catalogued as rs778253892; called by muse, mutect2, varscan2
- DNAH10 | c.4573_4588delinsAA p.E1525Nfs*7 (on ENST00000409039; = p.E1464Nfs*7 on NM_207437.3) | Frame Shift Del (DEL) | VAF 29/243 reads (12%) | called by pindel, varscan2*
- DNAH17 | c.5331T>G p.S1777R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, varscan2
- ELAC1 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, varscan2
- LRRC37A3 | c.4753G>C p.A1585P | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, varscan2
- NAV3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFIX | c.264_265insCCTCT p.E89Pfs*7 | Frame Shift Ins (INS) | VAF 47/336 reads (14%) | called by mutect2, pindel*, varscan2
- PRORP | c.1346T>G p.L449R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ROS1 | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SOCS4 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THBS2 | c.2272C>G p.L758V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRRAP | c.3739C>T p.R1247* | Nonsense Mutation (SNP) | VAF 57/335 reads (17%) | called by muse, mutect2, varscan2
- ZBTB4 | c.2291G>T p.R764L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- CCDC168 | c.4332T>A p.T1444= | Silent (SNP) | VAF 12/53 reads (23%) | called by mutect2, varscan2
- EHD1 | c.720G>T p.L240= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- MYBPHL | c.633C>T p.I211= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as rs148659131; called by muse, mutect2, varscan2
- PDE10A | c.283C>A p.R95= | Silent (SNP) | VAF 14/102 reads (14%) | called by mutect2, varscan2
- PRKD1 | c.2157T>C p.P719= | Silent (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- TNPO2 | c.1101G>T p.L367= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV63509232; called by muse, mutect2
- COL9A1 | c.-9A>G | 5'UTR (SNP) | VAF 39/217 reads (18%) | catalogued as rs760852894; called by muse, mutect2, varscan2
- DNAH8 | c.-226G>A | 5'UTR (SNP) | VAF 16/87 reads (18%) | catalogued as rs1221155183, COSV59474262; called by mutect2, varscan2
- FASTK | c.686-14del | Intron (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- LINC02520 | n.242C>T | RNA (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- PIGQ | c.1531+339C>A | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PLOD1 | c.-46C>T | 5'UTR (SNP) | VAF 9/90 reads (10%) | catalogued as rs923780490; called by muse, mutect2
